National Lung Screening Trial (NLST) participant 126606 — screening results and lung cancer
Open-access record from the public subset of National Lung Screening Trial clinical data distributed by the NCI Imaging Data Commons (release v24, collection nlst). NLST enrolled current and former heavy smokers aged 55–74 in 2002–2004 and randomised them to three annual screens (T0, T1, T2) with low-dose CT or chest radiography, with follow-up through 2009. Coded values are written out from the NLST data dictionaries; day counts are days from randomisation.
https://doi.org/10.7937/TCIA.HMQ8-J677

Participant
Age at randomisation: 62 years; Gender: female; Race: White; Cigarette smoking status at randomisation: current smoker; Enrolled through a Lung Screening Study (LSS) centre (from the participant ID range).

Screening results (official result of each annual screen after comparison with prior images; no CT screening exam record exists for this participant — in this public subset that is the pattern of the chest-radiography arm: every CT screen with a result has an exam record, and the subset has no trial-arm field)
- T0 (day 48): Negative screen, no significant abnormalities.
- T1 (day 470): Negative screen, no significant abnormalities.
- T2 (day 706): Negative screen, minor abnormalities not suspicious for lung cancer.

Lung cancer (1 primary lung cancer record; the first confirmed lung cancer occurred after the screening years; study year of the first confirmed lung cancer: T4; the diagnosis is not linked to a positive screen by the trial's diagnostic-procedure linking algorithm)
1. First primary lung cancer, diagnosed day 1,729, study year T4. Site: lung, NOS (ICD-O-3 C34.9), determined from histology. Primary tumour location: unknown location. Histology: small cell carcinoma, NOS (ICD-O-3 8041/3). Grade: cannot be assessed (GX). AJCC 6th edition staging: stage IIIB (best stage, from pathologic TNM); clinical TX N3 M0 (stage IIIB); pathologic TX N3 M0 (stage IIIB). AJCC 7th edition staging: stage IIIB; clinical TX N3 M0; pathologic TX N3 M0. VALCSG stage (the small-cell staging system; ACRIN recorded it for all its lung cancers): limited.

Follow-up
Last known free of lung cancer: day 1,447.
